Somatic mutation profile of tumor specimen ALCH-B2WY-TTP1-A (aliquot ALCH-B2WY-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2WY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.6 years (28,697 days).
Specimen ALCH-B2WY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef71fc25-ea2e-4adc-bea6-74a9f058817b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2WY-NB1-A (Blood Derived Normal), aliquot ALCH-B2WY-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25db4e81-332f-4bd1-9c2f-c7241ad79410

The open-access MAF lists 189 somatic variants for this specimen: 121 protein-altering or splice-affecting, 40 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 40, Intron 16, Nonsense Mutation 9, RNA 6, Frame Shift Ins 3, 3'UTR 3, Frame Shift Del 2, 5'Flank 2, Splice Region 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- AGA | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99219537; called by muse, mutect2
- AQR | c.2124G>T p.Q708H | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.868); catalogued as rs930874430, COSV50059411; called by muse, mutect2
- CCDC50 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 57/487 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66669341; called by muse, mutect2, varscan2
- CFAP47 | c.7054A>G p.I2352V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as rs892757289; called by muse, mutect2, varscan2
- CFHR4 | c.860G>C p.R287T (on ENST00000367416 / NM_001201551.2; = p.R288T on NM_001201550.3) | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.968); catalogued as COSV99259971; called by muse, mutect2, varscan2
- CRTAC1 | c.839C>A p.A280E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs867269141, COSV53997547; called by mutect2, varscan2
- CTAGE9 | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 28/662 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1191361254; called by muse, mutect2
- CTNNA2 | c.1511C>A p.T504N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100562494; called by muse, mutect2
- CXorf21 | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV66762407; called by muse, mutect2
- DDR2 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906420; called by muse, mutect2, varscan2
- DDX55 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV53017616; called by muse, mutect2, varscan2
- HAUS5 | c.1501G>T p.G501W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99178865; called by muse, mutect2, varscan2
- HDC | c.1989G>T p.*663Yext*40 | Nonstop Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as rs1218350666; called by muse, mutect2, varscan2
- HOXB3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61143216; called by muse, varscan2
- IL3RA | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); catalogued as COSV58432706; called by muse, mutect2
- IQCC | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV52210013; called by muse, varscan2
- JMJD1C | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 18/251 reads (7%) | catalogued as COSV101232480; called by muse, mutect2
- KMT5B | c.605G>T p.R202I | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100070098; called by muse, mutect2
- LRP1B | c.2617G>T p.G873* | Nonsense Mutation (SNP) | VAF 17/146 reads (12%) | catalogued as COSV63341665, COSV63341757; called by muse, mutect2, varscan2
- LRP1B | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV101260574; called by muse, mutect2
- MTSS2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55380452; called by muse, mutect2, varscan2
- NCOA1 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 51/444 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV56039465; called by muse, mutect2, varscan2
- NF1 | c.5481C>G p.I1827M (on ENST00000358273 / NM_001042492.3; = p.I1806M on NM_000267.3) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as rs1555533607, COSV99049968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLGN1 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV64326205; called by muse, mutect2, varscan2
- OCA2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1280092718, COSV62349722; called by muse, mutect2
- OR2G6 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs377095325; called by muse, mutect2, varscan2
- OR2M7 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58740967; called by muse, mutect2, varscan2
- PCDHGA1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65295936; called by muse, mutect2, varscan2
- POU3F4 | c.642C>A p.D214E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64538693, COSV64540131; called by muse, mutect2, varscan2
- PYDC2 | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.388); catalogued as COSV101573358; called by muse, mutect2
- RBL1 | c.2244G>T p.K748N | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV60329394; called by muse, mutect2
- REV1 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1304501707, COSV51488413; called by muse, mutect2
- RGPD3 | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 26/427 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58749012; called by muse, mutect2
- SLITRK1 | c.1662C>A p.S554R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as rs754943039, COSV65675425, COSV65675711; called by muse, mutect2, varscan2
- SPANXN1 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV65122740; called by muse, mutect2
- TNNT1 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV52571493, COSV99402677; called by muse, mutect2, varscan2
- TNRC6B | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57294478; called by muse, mutect2, varscan2
- TTC14 | c.435G>C p.L145F | Missense Mutation (SNP) | VAF 24/654 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56010774; called by muse, mutect2
- TTN | c.33341-5T>C | Splice Region (SNP) | VAF 8/104 reads (8%) | catalogued as rs746126758; called by muse, mutect2
- USP48 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1379741064, COSV57607069; called by muse, mutect2, varscan2
- VWA3A | c.1689G>T p.M563I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV55394026; called by muse, mutect2, varscan2
- ZNF99 | c.1107C>G p.Y369* | Nonsense Mutation (SNP) | VAF 20/290 reads (7%) | catalogued as COSV68056230; called by muse, mutect2
- A2ML1 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2
- ACAN | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY3 | c.179_185del p.E60Gfs*86 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- ADD1 | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.308); called by muse, mutect2
- ADM | c.295A>T p.M99L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AGA | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALAS2 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by mutect2, varscan2
- ALPK2 | c.5860C>T p.L1954F | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AP1G1 | c.1936A>G p.T646A | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- ASGR1 | c.824G>C p.W275S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRINP2 | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- BRINP2 | c.2118C>A p.Y706* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- C6orf58 | c.471G>T p.R157S | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.033); called by muse, mutect2
- CD5L | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CDH19 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDHR3 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP20 | c.203A>T p.Y68F | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); called by muse, mutect2
- CHD7 | c.7729G>T p.G2577W | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CLASP1 | c.307G>C p.A103P | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2
- CUBN | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CYP2C18 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DDX1 | c.2092G>T p.G698C | Missense Mutation (SNP) | VAF 31/406 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- EP400 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ETV5 | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2
- EXOC6B | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.351); called by muse, mutect2
- FMN1 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GABRB3 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.285); called by muse, mutect2
- GGCX | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.95); called by muse, mutect2
- GLIPR1L2 | c.706T>C p.F236L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.196); called by muse, mutect2
- GLRX3 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- GOLGA6L2 | c.1585dup p.Q529Pfs*118 | Frame Shift Ins (INS) | VAF 11/82 reads (13%) | called by pindel, varscan2
- GOLGB1 | c.3499C>G p.L1167V | Missense Mutation (SNP) | VAF 44/383 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPLD1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GPR174 | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR42 | c.80T>A p.V27E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- HCN1 | c.1153T>A p.C385S | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- HERC2 | c.3487G>T p.G1163C | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- HGF | c.730A>T p.K244* | Nonsense Mutation (SNP) | VAF 32/433 reads (7%) | called by muse, mutect2
- HPSE2 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); called by muse, mutect2
- INPP5J | c.1936G>T p.G646C (on ENST00000331075 / NM_001284285.2; = p.G278C on NM_001002837.2) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KIF14 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LRRN3 | c.1877C>A p.T626N | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAGEH1 | c.562T>A p.S188T | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); called by muse, mutect2
- MPHOSPH9 | c.1552G>T p.V518L | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2
- MROH1 | c.3530A>G p.K1177R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- MYO1H | c.1633C>A p.H545N | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.017); called by muse, mutect2
- NEXMIF | c.1909A>T p.R637W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NUFIP2 | c.1501del p.D501Ifs*12 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | called by mutect2, pindel, varscan2
- OR13D1 | c.489G>T p.R163S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by mutect2, varscan2
- P2RY8 | c.122dup p.N41Kfs*302 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- PAPOLB | c.683T>A p.I228N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH15 | c.2664A>T p.Q888H | Missense Mutation (SNP) | VAF 29/452 reads (6%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PCF11 | c.1518G>T p.R506S | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PKHD1L1 | c.2150A>G p.K717R | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.532); called by muse, mutect2
- POLR3B | c.2990C>T p.P997L | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2
- POM121L2 | c.1400T>A p.L467Q | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.028); called by muse, mutect2
- PRKCG | c.1847G>T p.W616L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRB | c.4646G>C p.G1549A | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PTPRZ1 | c.3608C>A p.P1203H | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RALGDS | c.1726A>G p.M576V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RXFP1 | c.1613C>A p.T538N | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2
- SERPINA5 | c.756C>A p.C252* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- SLFN13 | c.2272C>T p.H758Y | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLITRK2 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- TGIF1 | c.265A>G p.T89A (on ENST00000330513 / NM_001374396.1; = p.T109A on NM_003244.4) | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TLR4 | c.679A>T p.R227W (on ENST00000355622 / NM_138554.5; = p.R187W on NM_003266.4) | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); called by muse, mutect2
- TNFSF10 | c.610A>C p.K204Q | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.37); called by muse, mutect2
- TRA2B | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- TSPYL5 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TTN | c.21472dup p.T7158Nfs*8 (on ENST00000591111; = p.T6231Nfs*8 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/104 reads (12%) | called by mutect2, pindel
- UBB | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, varscan2
- UNC13C | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC79 | c.1998G>T p.M666I (on ENST00000393151 / NM_001346218.2; = p.M489I on NM_020818.5) | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); called by muse, mutect2
- USH2A | c.8836G>T p.A2946S | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2
- USP24 | c.3782C>T p.T1261I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRN1 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF484 | c.1991A>G p.Y664C | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF556 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- ABCB7 | c.39C>A p.A13= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- ADGRA2 | c.3906A>G p.L1302= | Silent (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- AFF2 | c.3447G>A p.S1149= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs782742162, COSV53998702; ClinVar: likely benign; called by muse, mutect2, varscan2
- AP1G1 | c.1650C>A p.I550= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs774153086; called by muse, mutect2
- ARAP3 | c.1800G>T p.L600= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- ARMC2 | c.1638G>A p.T546= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs61731702; called by mutect2, varscan2
- BRD7 | c.1809T>C p.G603= | Silent (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- CATSPERG | c.3363C>T p.S1121= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs988032481, COSV53046795; called by muse, mutect2, varscan2
- COL11A1 | c.1689T>C p.P563= | Silent (SNP) | VAF 22/192 reads (11%) | called by muse, mutect2, varscan2
- COL22A1 | c.3645A>G p.P1215= | Silent (SNP) | VAF 23/222 reads (10%) | catalogued as rs1296461487; called by muse, mutect2, varscan2
- DGLUCY | c.1194G>C p.T398= | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- GJD2 | c.42G>T p.A14= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- GSDMA | c.1146C>T p.F382= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV52856978; called by muse, mutect2, varscan2
- KLHL10 | c.1350A>C p.A450= | Silent (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2, varscan2
- LSP1 | c.771C>T p.S257= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, varscan2
- MCPH1 | c.798A>G p.S266= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs760208686; called by muse, mutect2, varscan2
- MORN3 | c.117G>A p.V39= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- MYO9A | c.1710T>C p.F570= | Silent (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- NCKIPSD | c.1080C>T p.L360= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1259319012; called by muse, varscan2
- OR4K2 | c.717T>C p.T239= | Silent (SNP) | VAF 21/322 reads (7%) | catalogued as rs1385945578; called by muse, mutect2
- OR6V1 | c.900G>A p.Q300= | Silent (SNP) | VAF 5/30 reads (17%) | called by mutect2, varscan2
- OR8D4 | c.438T>A p.A146= | Silent (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- OR8K5 | c.667T>C p.L223= | Silent (SNP) | VAF 12/229 reads (5%) | catalogued as rs754976961, COSV57890845, COSV57891699; called by muse, mutect2
- PARP15 | c.696C>T p.S232= | Silent (SNP) | VAF 37/549 reads (7%) | called by muse, mutect2
- PCDHA7 | c.1434G>T p.S478= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs782041607, COSV65345956; called by muse, mutect2, varscan2
- PIR | c.348G>A p.L116= | Silent (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.7365G>A p.G2455= | Silent (SNP) | VAF 16/175 reads (9%) | catalogued as COSV65741073; called by muse, mutect2
- PLXNA4 | c.5160G>T p.L1720= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- PRKDC | c.12282A>G p.P4094= | Silent (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- PRKDC | c.3336C>A p.A1112= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- PTPN20 | c.597C>G p.R199= | Silent (SNP) | VAF 30/965 reads (3%) | called by muse, mutect2
- RTL1 | c.786C>A p.P262= | Silent (SNP) | VAF 7/27 reads (26%) | called by mutect2, varscan2
- SAMD7 | c.483G>A p.Q161= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1242755022, COSV59418867; called by muse, mutect2, varscan2
- SPECC1 | c.6G>T p.R2= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- TAF1L | c.4428G>T p.A1476= | Silent (SNP) | VAF 20/350 reads (6%) | catalogued as rs1479156062, COSV54256796; called by muse, mutect2
- TRAV10 | c.108G>A p.E36= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- TRBV30 | c.189G>T p.L63= | Silent (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- TTF2 | c.3426A>G p.S1142= | Silent (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.57411C>A p.V19137= (on ENST00000591111; = p.V11713= on NM_003319.4) | Silent (SNP) | VAF 12/96 reads (13%) | called by mutect2, varscan2
- TYRO3 | c.1956C>T p.I652= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- AC073648.1 | n.386T>A | RNA (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847361 C>A | 5'Flank (SNP) | VAF 10/45 reads (22%) | catalogued as rs893734458; called by muse, mutect2, varscan2
- ASH1L | c.5828+4486_5828+4488delinsTT | Intron (DEL) | VAF 37/239 reads (15%) | called by pindel, varscan2*
- CD200R1 | c.68-16697A>T | Intron (SNP) | VAF 24/428 reads (6%) | called by muse, mutect2
- DCX | c.-3A>T | 5'UTR (SNP) | VAF 12/72 reads (17%) | called by mutect2, varscan2
- DCX | c.-22-385C>T | Intron (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- DDR2 | c.1504+105G>T | Intron (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- ELOVL6 | c.221+12365G>C | Intron (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- FMR1 | c.*177G>A | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- GALNT12 | c.*30G>T | 3'UTR (SNP) | VAF 13/113 reads (12%) | catalogued as COSV100899171; called by muse, mutect2, varscan2
- HMGN2P46 | n.683-8324C>A | Intron (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2
- HNF4A | c.1129+80C>T | Intron (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100291747; called by muse, mutect2, varscan2
- LAMA4 | c.297+2360G>A | Intron (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- MSC-AS1 | n.418G>T | RNA (SNP) | VAF 22/311 reads (7%) | called by muse, mutect2
- MSC-AS1 | n.419G>T | RNA (SNP) | VAF 22/306 reads (7%) | called by muse, mutect2
- MUC19 | n.5781G>T | RNA (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- NDUFS3 | chr11:47579055 G>A | 5'Flank (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- PSMA8 | c.103-4483G>C | Intron (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- RFX6 | c.*18G>T | 3'UTR (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
- SPATA7 | c.94+167G>T | Intron (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- SPATA7 | c.94+168G>T | Intron (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- SSX6P | n.234A>T | RNA (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- TF | c.1687+13G>T | Intron (SNP) | VAF 12/145 reads (8%) | called by muse, mutect2
- TFPI | c.628+5435C>G | Intron (SNP) | VAF 14/118 reads (12%) | catalogued as COSV51904109; called by muse, mutect2
- TRBV25OR9-2 | n.138C>A | RNA (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- TTN | c.10360+1438G>T | Intron (SNP) | VAF 12/247 reads (5%) | catalogued as COSV100592363, COSV100634856; called by muse, mutect2
- ZNF211 | c.218-709C>A | Intron (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- ZZEF1 | c.7212+31T>C | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2
